Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NO, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NO-01A (Primary Tumor).

ICD-0-3

Carcinoma, hepatocellular NOS
817013

Site: Liver C22.0

gwd 12/24/12

REVISED REPORT (Addendum/Procedure included)

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10 A11 B1

Tissue from liver segments II and III (aggregating 163.0 grams, 12.8 x 9.2 x 6.8 cm), tissue from liver new margin (7.8 x 1.5 x 1.5 cm).

DIAGNOSIS:

Liver, segments II and III and new margin, excisions:
Well-differentiated hepatocellular carcinoma forming a 3.2 x 2.8 x 2.2 cm well-circumscribed but unencapsulated mass. No vascular invasion seen. Surgical resection margins, after a single re-excision are negative for tumor.

ADDENDUM:

The surrounding non-neoplastic liver shows mild, nonspecific portal inflammation with no advanced fibrosis (see comment).

ADDENDUM COMMENT:

A minority of portal tracts contain a mixed inflammatory infiltrate consisting of lymphocytes with rare plasma cells and occasional neutrophils. The latter appear to be associated with patchy ductular proliferation. Interlobular bile ducts are intact. A solitary portal-based granulomatous reaction is seen. The lobular parenchyma demonstrates surgical hepatitis with trace steatosis but no active steatohepatitis. There is no significant fibrosis.

Source: NCI Genomic Data Commons file e1e1308c-b203-497f-bd57-c26e0a357953 (TCGA-DD-A4NO.0B108361-E361-4A8B-9F5C-FC3ACB992DB9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).